Somatic mutation profile of tumor specimen TCGA-CV-6959-01A (aliquot TCGA-CV-6959-01A-11D-1912-08) from TCGA case TCGA-CV-6959, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 48.4 years (17,679 days).
Specimen TCGA-CV-6959-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96c7c201-f62a-46e7-9ff2-433d5bee3c9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6959-10A (Blood Derived Normal), aliquot TCGA-CV-6959-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64018060-0ffc-4e48-b660-5f16db995ddd

The open-access MAF lists 67 somatic variants for this specimen: 46 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 18, Nonsense Mutation 4, Frame Shift Del 4, Intron 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 15/29 reads (52%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- RASA1 | c.1534C>T p.R512* | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | catalogued as rs1554048066, CM1311704, COSV57191996; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.294_297del p.S99Rfs*23 | Frame Shift Del (DEL) | VAF 66/127 reads (52%) | catalogued as rs730882015; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACTL7B | c.635G>C p.G212A | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101012580; called by muse, varscan2
- AIPL1 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.046); catalogued as COSV100006181; called by muse, mutect2, varscan2
- AMIGO3 | c.1294_1295del p.Q432Vfs*42 | Frame Shift Del (DEL) | VAF 22/123 reads (18%) | catalogued as rs768205240; called by pindel, varscan2
- ATP2B3 | c.881C>G p.A294G | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV99685660; called by muse, varscan2
- BEND7 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.042); catalogued as rs377375734; called by muse, mutect2, varscan2
- BPIFB2 | c.656C>A p.S219Y | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV99401012, COSV99401641; called by muse, varscan2
- CASP3 | c.332G>A p.R111K | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.777); catalogued as COSV100395062; called by muse, mutect2, varscan2
- CHL1 | c.3436G>T p.G1146* (on ENST00000397491 / NM_001253387.1; = p.G1162* on NM_006614.4) | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as COSV56585444, COSV99852205; called by muse, mutect2, varscan2
- CPAMD8 | c.2878G>A p.A960T (on ENST00000651564; = p.A913T on NM_015692.5) | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs529234664, COSV101488516, COSV101488587; called by muse, mutect2, varscan2
- DOP1A | c.7039G>A p.E2347K | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52712489, COSV99382803; called by muse, mutect2, varscan2
- FAM47A | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.835); catalogued as rs760796124, COSV60498449; called by muse, mutect2, varscan2
- FAT1 | c.12067C>T p.Q4023* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | catalogued as COSV71676695; called by muse, mutect2, varscan2
- HCN4 | c.1139C>T p.T380M | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56086245; called by muse, mutect2, varscan2
- HECW1 | c.1945G>A p.D649N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as rs769155947, COSV67840542; called by muse, mutect2, varscan2
- HECW2 | c.1307G>T p.C436F | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.094); catalogued as COSV53668769, COSV99648734; called by muse, mutect2
- HPD | c.322C>A p.Q108K | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.992); catalogued as COSV100000211; called by muse, mutect2, varscan2
- KRT83 | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99531875; called by muse, mutect2, varscan2
- LRRK2 | c.5365G>C p.E1789Q | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs757331822, COSV100111056; called by muse, mutect2, varscan2
- MEGF9 | c.461C>A p.P154Q | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100879530; called by muse, mutect2, varscan2
- MTCL1 | c.1688G>C p.R563P (on ENST00000306329 / NM_001378206.1; = p.R203P on NM_015210.4) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100095468; called by muse, varscan2
- NOL4 | c.740A>G p.Q247R | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (1); PolyPhen probably damaging (0.946); catalogued as COSV99306680; called by muse, mutect2, varscan2
- NOTCH1 | c.2635C>T p.R879W | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs587778563, COSV53053683; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- OXER1 | c.283C>G p.L95V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV99685534; called by muse, mutect2, varscan2
- PCDHGB4 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376966829, COSV99545960; called by muse, mutect2, varscan2
- RIMS1 | c.2993G>A p.R998Q | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as rs1414432029, COSV53450436; called by muse, mutect2, varscan2
- ROBO1 | c.2085G>C p.W695C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101459219; called by muse, mutect2, varscan2
- SBSN | c.1409G>A p.G470E (on ENST00000452271 / NM_001166034.2; = p.G127E on NM_198538.4) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.928); catalogued as COSV101510103; called by muse, mutect2, varscan2
- SCN10A | c.4766C>T p.A1589V | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs753004431, COSV71860872; called by muse, mutect2, varscan2
- SEMA4F | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as rs371410540, COSV100336138; called by muse, mutect2, varscan2
- SERPINB8 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV99729388; called by muse, mutect2, varscan2
- SIPA1L3 | c.3832G>A p.A1278T | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.975); catalogued as rs762325718, COSV99730300; called by muse, mutect2, varscan2
- SIRT3 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.055); catalogued as rs765568528, COSV101236029; called by muse, mutect2, varscan2
- SLC16A14 | c.803C>A p.P268H | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99725857; called by muse, mutect2, varscan2
- TET1 | c.6172C>A p.Q2058K | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0.024); catalogued as COSV101018836; called by muse, mutect2, varscan2
- TNFRSF10B | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.925); catalogued as rs750099768, COSV99375613; called by mutect2, varscan2
- TSGA10 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs554381768, COSV100747771; called by muse, mutect2, varscan2
- VPS13A | c.5978G>T p.R1993L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769890530, COSV100653411, COSV62429175; called by muse, mutect2, varscan2
- XKR4 | c.604G>T p.A202S | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV100533854; called by muse, mutect2, varscan2
- ZMYND11 | c.1419G>C p.K473N | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV100556895; called by muse, mutect2, varscan2
- ZNF560 | c.165G>T p.Q55H | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV100038989; called by muse, mutect2, varscan2
- LHX1 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- MUC16 | c.25618_25619del p.M8540Efs*2 | Frame Shift Del (DEL) | VAF 13/86 reads (15%) | called by mutect2, pindel, varscan2
- MYO1D | c.744_745del p.R248Sfs*4 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | called by pindel, varscan2
- AC126283.2 | c.1212T>C p.L404= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV101144693; called by muse, mutect2
- ADAMTS18 | c.234C>T p.H78= | Silent (SNP) | VAF 58/361 reads (16%) | catalogued as rs369294701; called by muse, mutect2, varscan2
- CD247 | c.132C>G p.V44= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV100758469; called by muse, mutect2
- EHMT2 | c.3613C>T p.L1205= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV99999249; called by muse, mutect2, varscan2
- FAM155B | c.531C>A p.A177= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs142803076, COSV99368647; called by muse, mutect2, varscan2
- FAM83C | c.747G>A p.G249= | Silent (SNP) | VAF 22/542 reads (4%) | catalogued as COSV100981690; called by muse, mutect2
- GPN2 | c.333C>T p.C111= | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as COSV100658900; called by muse, mutect2, varscan2
- GRM1 | c.3447G>A p.S1149= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs749505813, COSV51283867; called by muse, mutect2, varscan2
- H3C11 | c.174G>A p.S58= | Silent (SNP) | VAF 24/176 reads (14%) | catalogued as rs1279299235, COSV100138063; called by muse, mutect2, varscan2
- LRRN3 | c.435C>A p.L145= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100073083; called by muse, mutect2
- NAV2 | c.6207C>G p.V2069= (on ENST00000396087 / NM_001244963.2; = p.V2010= on NM_145117.5) | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV100217590, COSV60661681; called by muse, mutect2, varscan2
- OR14C36 | c.936G>A p.V312= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as rs1416930646, COSV100507636; called by muse, mutect2, varscan2
- PCDH19 | c.891G>T p.L297= | Silent (SNP) | VAF 45/91 reads (49%) | catalogued as COSV99720678; called by muse, mutect2, varscan2
- RFX2 | c.459C>A p.I153= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100353977; called by muse, mutect2
- RHO | c.309C>T p.F103= | Silent (SNP) | VAF 22/176 reads (13%) | catalogued as rs149615742; called by muse, mutect2, varscan2
- SFI1 | c.2190G>C p.V730= (on ENST00000400288 / NM_001007467.3; = p.V699= on NM_014775.4) | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV101192262; called by muse, mutect2
- SLC18A3 | c.1440C>T p.S480= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV60335491; called by muse, mutect2, varscan2
- TTN | c.14133C>T p.V4711= (on ENST00000591111; = p.V3784= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV100627553; called by muse, mutect2, varscan2
- IRX6 | c.*1C>T | 3'UTR (SNP) | VAF 14/90 reads (16%) | catalogued as COSV51861161; called by muse, mutect2, varscan2
- KIF1B | c.2115+6851C>G | Intron (SNP) | VAF 31/142 reads (22%) | catalogued as COSV99822384, COSV99824078; called by muse, mutect2, varscan2
- MIR506 | n.92G>T | RNA (SNP) | VAF 47/75 reads (63%) | called by muse, mutect2, varscan2
